Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0W1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0W1-01A (Primary Tumor).

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium, NOS C54.1

5/11/11

UJID:BE7CC54D-8220-4AC6-9F8D-016DE4167835

PATIENT HISTORY:

Not provided. LMP: Not provided.

PRE-OP DIAGNOSIS: Endometrial cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, lymph node

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 4.6 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 75 %, Posterior endomyometrium: 75 %

DEPTH OF INVASION:**

Less than 1/2 thickness of myometrium

STRUCTURES INVOLVED:

Endocervical glands

MARGINS OF RESECTION:

Vaginal margin is negative for tumor, Parametrium margin is negative for tumor

ANGIOLYMPHATIC INVASION:

No

PRE-NEOPLASTIC CONDITIONS:

Simple endometrial hyperplasia with atypia, Complex endometrial hyperplasia without atypia

OTHER:

(epithelial, smooth muscle, others), Adenomyosis, Leiomyoma

MITOTIC RATE:

Mitotic rate: 15 / 10 HPF

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 12

EXTRANODAL EXTENSION:

No

DISTANT METASTASES (Excludes metastases to vagina, pelvic serosa, and adnexa. Includes lymph nodes other than regional lymph nodes.):

Absent

T STAGE, PATHOLOGIC:

pT2a

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIA

RESIDUAL TUMOR:

RX

Comment:

Peritoneal washing

is reported as negative for malignant cells.

FIGO Discrepancy		

Source: NCI Genomic Data Commons file 0a249094-a169-47b8-8834-b03da7e4838c (TCGA-BG-A0W1.BE7CC54D-8220-4AC6-9F8D-016DE4167B35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).